Somatic mutation profile of tumor specimen MMRF_1466_3_BM_CD138pos (aliquot MMRF_1466_3_BM_CD138pos_T1_KHS5U_L12880) from MMRF case MMRF_1466, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.6 years (25,798 days).
Specimen MMRF_1466_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93d5c39c-3a85-4e41-baab-4d78a50782cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1466_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1466_1_PB_Whole_C2_KAS5U_L01384; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/604b9714-30a8-4538-a95b-b27b5a283c5d

The open-access MAF lists 229 somatic variants for this specimen: 97 protein-altering or splice-affecting, 26 silent, 106 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, 3'UTR 56, Intron 32, Silent 26, 5'UTR 7, 3'Flank 5, 5'Flank 5, Splice Region 4, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 51/104 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCA6 | c.4690G>C p.E1564Q | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52635928; called by muse, mutect2
- ANGPT4 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV67922724; called by muse, mutect2, varscan2
- ANKRD1 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV65468146; called by muse, mutect2
- AOX1 | c.2655+1G>A p.X885_splice | Splice Site (SNP) | VAF 21/54 reads (39%) | catalogued as rs199507417, COSV65981337; called by muse, mutect2, varscan2
- ATR | c.5915C>T p.A1972V | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63389837; called by muse, mutect2, varscan2
- BAZ2B | c.52A>C p.T18P | Missense Mutation (SNP) | VAF 85/190 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.147); catalogued as rs373390123; called by muse, mutect2, varscan2
- CORO6 | c.283_285del p.N95del | In Frame Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs1567809906; called by mutect2, pindel, varscan2
- CYP2A13 | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.548); catalogued as COSV100387046; called by muse, mutect2, varscan2
- DCAF4 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 16/235 reads (7%) | catalogued as rs1424865442, COSV62319356; called by muse, mutect2
- FREM3 | c.4903C>G p.L1635V | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV61679263; called by muse, mutect2
- GFI1B | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761729738, COSV59743876; called by muse, mutect2, varscan2
- GRM5 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776804851, COSV59590843; called by muse, mutect2, varscan2
- ILF3 | c.2412G>T p.E804D | Missense Mutation (SNP) | VAF 33/329 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV99139705; called by muse, mutect2
- ITIH1 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.251); catalogued as rs138161449; called by muse, mutect2, varscan2
- MESP2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as rs1257292132; called by muse, mutect2
- MPEG1 | c.1553A>G p.Y518C | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV57094093; called by muse, mutect2, varscan2
- NOP2 | c.1252A>G p.N418D (on ENST00000322166 / NM_001258308.2; = p.N414D on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs752863516; called by muse, mutect2, varscan2
- PCDHA5 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.018); catalogued as rs1341974527; called by muse, mutect2, varscan2
- PRDM1 | c.2291G>A p.R764K | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV64844296, COSV64846264; called by muse, mutect2, varscan2
- PRUNE2 | c.5358G>T p.K1786N | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs758711625; called by muse, mutect2, varscan2
- PSAPL1 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs761015476; called by muse, mutect2, varscan2
- RASL11A | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 8/240 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54080897; called by muse, mutect2
- RIC1 | c.2686C>G p.L896V | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.81); catalogued as rs913391344; called by muse, mutect2
- SBK3 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs537976523; called by muse, mutect2, varscan2
- SEPTIN10 | c.635C>A p.T212K | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61780415; called by muse, mutect2, varscan2
- STX1A | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as rs201037992, COSV56094921; called by muse, mutect2
- TPRXL | n.397G>A | Splice Region (SNP) | VAF 71/251 reads (28%) | catalogued as rs1328606298; called by muse, mutect2, varscan2
- ZNF264 | c.1448A>G p.Y483C | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs1411980599; called by muse, mutect2, varscan2
- AHNAK | c.14834A>C p.K4945T | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); called by muse, mutect2
- BMS1 | c.1889G>C p.G630A | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- C11orf87 | c.380_385del p.K127_E128del | In Frame Del (DEL) | VAF 78/199 reads (39%) | called by mutect2, pindel, varscan2
- CCNC | c.40T>G p.W14G | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEBPA | c.255C>G p.S85R | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2
- CLCN6 | c.83A>T p.E28V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CPN1 | c.1184A>C p.D395A | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTTNBP2 | c.3964C>A p.L1322M | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- CXCR4 | c.969_972dup p.S325Vfs*20 | Frame Shift Ins (INS) | VAF 18/45 reads (40%) | called by mutect2, pindel, varscan2
- DAAM1 | c.2254G>C p.D752H | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.688); called by muse, mutect2
- DSG4 | c.3029A>G p.D1010G | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- EDF1 | c.6del p.E3Rfs*7 | Frame Shift Del (DEL) | VAF 65/349 reads (19%) | called by mutect2, pindel, varscan2
- ENO4 | c.1311C>A p.Y437* (on ENST00000622726; = p.Y434* on NM_001242699.2) | Nonsense Mutation (SNP) | VAF 50/132 reads (38%) | called by muse, mutect2, varscan2
- EYA1 | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- EYS | c.1882A>G p.N628D | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- FAM47C | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.051); called by muse, mutect2
- GP5 | c.739T>A p.L247M | Missense Mutation (SNP) | VAF 17/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPATCH2 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.339); called by muse, mutect2
- H1-4 | c.191A>T p.K64I | Missense Mutation (SNP) | VAF 109/185 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HCFC1 | c.2564G>T p.R855L | Missense Mutation (SNP) | VAF 69/97 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IDO1 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- IGHV1-69D | c.62T>A p.V21E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by mutect2, varscan2
- IGLV3-1 | c.208_211delinsTAT p.S70Yfs*22 | Frame Shift Del (DEL) | VAF 73/135 reads (54%) | called by pindel, varscan2*
- IGSF22 | c.2353C>A p.Q785K (on ENST00000319338; = p.Q886K on NM_173588.4) | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.05); called by muse, mutect2
- IL25 | c.200C>G p.P67R | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.014); called by muse, mutect2
- INAVA | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- KATNA1 | c.1370C>G p.T457R | Missense Mutation (SNP) | VAF 18/419 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- KIF1A | c.3959G>A p.S1320N (on ENST00000320389 / NM_001379639.1; = p.S1312N on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- KLKB1 | c.265A>G p.K89E | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- LIPA | c.918A>C p.Q306H | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2
- LIPM | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2
- MIR29B2CHG | n.409G>T | Splice Region (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- MOCOS | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 95/184 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEFM | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NHSL1 | c.1520T>A p.L507Q | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2
- NUFIP1 | c.1136_1137del p.E379Gfs*7 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- NWD1 | c.4522G>A p.A1508T | Missense Mutation (SNP) | VAF 26/548 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- OR12D3 | c.161A>G p.H54R | Missense Mutation (SNP) | VAF 144/208 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR4C15 | c.963C>A p.D321E (on ENST00000314644; = p.D267E on NM_001001920.2) | Missense Mutation (SNP) | VAF 179/419 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- OR5D13 | c.280A>T p.I94F | Missense Mutation (SNP) | VAF 108/434 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- OSBPL9 | c.1624+4A>C | Splice Region (SNP) | VAF 17/220 reads (8%) | called by muse, mutect2
- PDILT | c.1751T>G p.L584R | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PDP2 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.041); called by muse, mutect2
- PIEZO2 | c.179T>C p.L60S | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2
- PLCZ1 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2
- PPEF2 | c.1400T>G p.F467C | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBM26 | c.1024C>G p.P342A | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RPS6KA3 | c.1691T>A p.F564Y | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- SCN3A | c.1708A>G p.R570G | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2
- SEC23B | c.593A>T p.K198M | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); called by muse, mutect2
- SEC24D | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 23/273 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- SERPINB10 | c.14C>A p.A5E | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- SIRT1 | c.1543C>G p.P515A | Missense Mutation (SNP) | VAF 6/196 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2
- SLC38A9 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- SLC5A5 | c.1172-4A>G | Splice Region (SNP) | VAF 33/125 reads (26%) | called by muse, mutect2, varscan2
- SSH1 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); called by muse, mutect2
- TANC1 | c.4594C>A p.Q1532K | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- TBC1D9B | c.1535G>T p.S512I | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2
- TBRG4 | c.1892A>C p.K631T | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2
- TEKT3 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.325); called by muse, mutect2
- TENM3 | c.191A>C p.K64T | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TNC | c.5773G>A p.D1925N | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TNFRSF1A | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- TRIO | c.2951T>A p.M984K | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TRPC1 | c.1466G>C p.W489S (on ENST00000476941 / NM_001251845.2; = p.W455S on NM_003304.4) | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TSPYL6 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 170/373 reads (46%) | called by muse, mutect2, varscan2
- ZBTB6 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 27/541 reads (5%) | called by muse, mutect2
- ZNF512B | c.1456G>T p.A486S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.025); called by muse, mutect2
- ADCY3 | c.66C>T p.V22= | Silent (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- ANK3 | c.9243C>A p.A3081= | Silent (SNP) | VAF 15/167 reads (9%) | called by muse, mutect2
- ANKRD42 | c.24C>A p.G8= | Silent (SNP) | VAF 57/213 reads (27%) | called by muse, mutect2, varscan2
- APBB2 | c.1038C>T p.N346= (on ENST00000295974 / NM_001166050.2; = p.N347= on NM_004307.2) | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs757004371; called by muse, varscan2
- ATF6B | c.45T>C p.R15= | Silent (SNP) | VAF 267/451 reads (59%) | called by muse, mutect2, varscan2
- CADPS2 | c.978G>A p.S326= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as rs772232660, COSV57348365; called by muse, mutect2, varscan2
- CLPB | c.507A>G p.T169= | Silent (SNP) | VAF 22/420 reads (5%) | called by muse, mutect2
- FGD5 | c.885A>G p.E295= | Silent (SNP) | VAF 18/408 reads (4%) | called by muse, mutect2
- GGN | c.822C>T p.G274= | Silent (SNP) | VAF 12/194 reads (6%) | catalogued as COSV53057229; called by muse, mutect2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 28/48 reads (58%) | catalogued as rs376111067; called by muse, varscan2
- IGHV2-70 | c.198G>T p.L66= | Silent (SNP) | VAF 80/162 reads (49%) | catalogued as rs562646171; called by muse, varscan2
- INTS1 | c.4647C>A p.I1549= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs777754949, COSV67179898; called by muse, mutect2, varscan2
- LDB2 | c.1005C>T p.D335= | Silent (SNP) | VAF 103/248 reads (42%) | catalogued as rs749480922; called by muse, mutect2, varscan2
- MAP3K15 | c.2229G>C p.G743= | Silent (SNP) | VAF 105/243 reads (43%) | called by muse, mutect2, varscan2
- OR51C1P | c.27C>T p.S9= | Silent (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- OSBPL5 | c.99C>T p.L33= | Silent (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- PATE2 | c.42C>T p.C14= | Silent (SNP) | VAF 13/330 reads (4%) | catalogued as rs1412868707; called by muse, mutect2
- POLQ | c.5694C>G p.T1898= | Silent (SNP) | VAF 13/373 reads (3%) | catalogued as COSV51745191; called by muse, mutect2
- SRARP | c.75C>G p.T25= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV100273133; called by muse, mutect2
- TENM1 | c.1869C>T p.C623= | Silent (SNP) | VAF 56/207 reads (27%) | catalogued as rs1322148554, COSV64431434, COSV64446882; called by muse, mutect2, varscan2
- THAP10 | c.93G>A p.L31= | Silent (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- TNXB | c.2589C>T p.P863= | Silent (SNP) | VAF 70/244 reads (29%) | catalogued as rs1226619179; called by muse, mutect2, varscan2
- TRAJ35 | c.45A>G p.Q15= | Silent (SNP) | VAF 9/166 reads (5%) | called by muse, mutect2
- TRIOBP | c.3399C>T p.S1133= | Silent (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- TSHZ1 | c.501C>A p.T167= (on ENST00000580243 / NM_001308210.2; = p.T122= on NM_005786.6) | Silent (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
- ZNF606 | c.84C>T p.S28= | Silent (SNP) | VAF 60/213 reads (28%) | called by muse, mutect2, varscan2
- ABCB5 | c.1707+1292G>A | Intron (SNP) | VAF 9/24 reads (38%) | catalogued as rs1373547178; called by muse, mutect2, varscan2
- ABLIM3 | c.*650C>A | 3'UTR (SNP) | VAF 17/209 reads (8%) | called by muse, mutect2
- ACSL3 | c.556+116G>T | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.1370+2823G>A | Intron (SNP) | VAF 45/75 reads (60%) | catalogued as rs865938382; called by muse, mutect2, varscan2
- ANKRD18A | chr9:38622816 G>T | 5'Flank (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.105+151A>C | Intron (SNP) | VAF 25/164 reads (15%) | called by muse, mutect2, varscan2
- ATG4C | c.*484T>C | 3'UTR (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- AVPR1A | c.-83G>T | 5'UTR (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- BRS3 | c.*553G>A | 3'UTR (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- BRWD1 | c.*1779C>T | 3'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- BTBD9 | c.*5356G>A | 3'UTR (SNP) | VAF 7/94 reads (7%) | catalogued as rs905943134; called by muse, mutect2
- BUB3 | c.*773G>A | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- C4orf46 | c.*2506C>G | 3'UTR (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- CAPN5 | c.*207T>G | 3'UTR (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- CCDC30 | c.385-8126C>T | Intron (SNP) | VAF 9/98 reads (9%) | catalogued as rs1211537342; called by muse, mutect2
- CCSER2 | c.*2243G>A | 3'UTR (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- CLDN1 | c.*281T>A | 3'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- CLEC5A | c.*649C>A | 3'UTR (SNP) | VAF 12/139 reads (9%) | called by muse, mutect2
- CUL4B | chrX:120525139 T>G | 3'Flank (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- DUOXA2 | c.148-228G>T | Intron (SNP) | VAF 26/96 reads (27%) | called by muse, mutect2, varscan2
- EEF2K | c.*1073A>T | 3'UTR (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- EIF1AD | c.*333C>T | 3'UTR (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- EPHA5 | c.3008+1125C>T | Intron (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- ERBB4 | c.*1518A>T | 3'UTR (SNP) | VAF 53/107 reads (50%) | called by muse, mutect2, varscan2
- ESR1 | c.*3017C>T | 3'UTR (SNP) | VAF 31/99 reads (31%) | catalogued as rs1465371516; called by muse, mutect2, varscan2
- ESRP1 | chr8:94639229 C>T | 5'Flank (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- FAM102B | c.*3850G>A | 3'UTR (SNP) | VAF 25/36 reads (69%) | catalogued as rs921529335; called by muse, mutect2, varscan2
- FGD4 | c.2043+34G>T | Intron (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- GAPT | chr5:58496869 C>G | 3'Flank (SNP) | VAF 14/264 reads (5%) | called by muse, mutect2
- GDAP1L1 | c.374-191T>G | Intron (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- GNAQ | c.*3687C>A | 3'UTR (SNP) | VAF 58/126 reads (46%) | called by muse, mutect2, varscan2
- GNPDA2 | c.770-1346T>A | Intron (SNP) | VAF 10/26 reads (38%) | catalogued as rs888719761; called by muse, mutect2, varscan2
- GOLT1B | c.117+116C>G | Intron (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- GULP1 | c.844-2497A>G | Intron (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102094G>T | Intron (SNP) | VAF 23/799 reads (3%) | called by muse, mutect2
- HS1BP3 | c.*681G>C | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- IARS1 | c.-90A>C | 5'UTR (SNP) | VAF 127/583 reads (22%) | called by muse, mutect2, varscan2
- IFFO2 | c.*3677G>C | 3'UTR (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- IGDCC4 | c.*549G>T | 3'UTR (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- IMPA2 | c.231-1369T>G | Intron (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- KCNK1 | c.*337T>G | 3'UTR (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- KIAA1143 | c.*1013G>A | 3'UTR (SNP) | VAF 33/142 reads (23%) | called by muse, mutect2, varscan2
- KIF6 | c.*5463G>A | 3'UTR (SNP) | VAF 297/480 reads (62%) | catalogued as rs1002565173; called by muse, mutect2, varscan2
- KNOP1P1 | n.383T>G | RNA (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- LARP1B | c.1524+328del | Intron (DEL) | VAF 130/310 reads (42%) | called by mutect2, pindel, varscan2
- LDHB | c.*160A>T | 3'UTR (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- LINC01511 | n.437-8979A>G | Intron (SNP) | VAF 8/136 reads (6%) | catalogued as rs1463726930; called by muse, mutect2
- LY6K | c.218-304C>G | Intron (SNP) | VAF 21/280 reads (8%) | called by muse, mutect2
- LYPLA2 | c.*336T>G | 3'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- MCC | chr5:113488606 C>T | 5'Flank (SNP) | VAF 40/132 reads (30%) | called by muse, mutect2, varscan2
- MGAT5 | c.*3863C>T | 3'UTR (SNP) | VAF 22/46 reads (48%) | catalogued as rs1170968567; called by muse, mutect2, varscan2
- Metazoa_SRP | chr15:62243290 G>A | 3'Flank (SNP) | VAF 20/276 reads (7%) | catalogued as rs895784279; called by muse, mutect2
- NMUR2 | c.*313C>A | 3'UTR (SNP) | VAF 26/104 reads (25%) | called by muse, mutect2, varscan2
- NPHS1 | c.2213-70A>C | Intron (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2
- NUP98 | c.2793+844A>C | Intron (SNP) | VAF 9/165 reads (5%) | called by muse, mutect2
- OXR1 | c.224-21264G>A | Intron (SNP) | VAF 88/132 reads (67%) | catalogued as rs1214963105; called by muse, mutect2
- PATJ | c.*197A>T | 3'UTR (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
- PCDH1 | c.*339A>G | 3'UTR (SNP) | VAF 52/190 reads (27%) | called by muse, mutect2, varscan2
- PCDHB10 | c.*438A>T | 3'UTR (SNP) | VAF 29/107 reads (27%) | called by muse, mutect2, varscan2
- PCNA | c.-122T>G | 5'UTR (SNP) | VAF 130/324 reads (40%) | called by muse, mutect2, varscan2
- PEX5L | c.*1756G>T | 3'UTR (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- PI15 | c.*1392C>A | 3'UTR (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- POF1B | c.*446A>T | 3'UTR (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- POLR1C | c.249+85T>C | Intron (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- PRKAA2 | c.*2875G>A | 3'UTR (SNP) | VAF 32/55 reads (58%) | called by muse, mutect2, varscan2
- PRSS1 | c.200+14C>T | Intron (SNP) | VAF 36/96 reads (38%) | called by muse, varscan2
- PSAT1 | c.*402G>A | 3'UTR (SNP) | VAF 9/182 reads (5%) | called by muse, mutect2
- PURA | c.*619C>T | 3'UTR (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- PURB | c.*7161A>C | 3'UTR (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- PYGO1 | c.*4344A>T | 3'UTR (SNP) | VAF 5/140 reads (4%) | called by muse, mutect2
- RAPGEF5 | c.871-233_871-218delinsAG | Intron (DEL) | VAF 18/48 reads (38%) | called by pindel, varscan2*
- REV3L | c.-288G>A | 5'UTR (SNP) | VAF 63/194 reads (32%) | called by muse, mutect2, varscan2
- RFFL | c.*491G>A | 3'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- RIMS1 | chr6:72400900 T>C | 3'Flank (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99326839; called by muse, mutect2, varscan2
- SCN8A | c.*633A>T | 3'UTR (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- SEC23A | c.*498A>C | 3'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- SENP1 | c.*1687A>G | 3'UTR (SNP) | VAF 11/20 reads (55%) | catalogued as rs1167592664; called by muse, mutect2, varscan2
- SLC12A5 | c.924-343G>A | Intron (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- SLC16A2 | c.*1285G>T | 3'UTR (SNP) | VAF 8/91 reads (9%) | called by muse, mutect2
- SLC22A8 | c.1325+48G>C | Intron (SNP) | VAF 10/227 reads (4%) | called by muse, mutect2
- SLIT3 | c.1459+4558G>T | Intron (SNP) | VAF 11/157 reads (7%) | catalogued as rs1476940494; called by muse, mutect2
- SLITRK6 | c.*130A>T | 3'UTR (SNP) | VAF 6/81 reads (7%) | catalogued as COSV101233313; called by muse, mutect2
- SMAD4 | c.*6301G>C | 3'UTR (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- SNTN | c.*368G>A | 3'UTR (SNP) | VAF 48/75 reads (64%) | called by muse, mutect2, varscan2
- SRRM4 | c.*3872C>A | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.*4521C>A | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- TERB2 | c.*577T>A | 3'UTR (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- TMC5 | c.1049-3668T>A | Intron (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975184 C>T | 5'Flank (SNP) | VAF 75/179 reads (42%) | called by muse, mutect2, varscan2
- TOM1L1 | c.1034-27G>C | Intron (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- TPTE | c.-3C>T | 5'UTR (SNP) | VAF 136/601 reads (23%) | catalogued as rs754765553; called by muse, mutect2, varscan2
- TSPAN14 | chr10:80520434 G>C | 3'Flank (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- TTC29 | c.-7+2384G>T | Intron (SNP) | VAF 48/101 reads (48%) | catalogued as rs1017351264; called by muse, mutect2, varscan2
- TTC7A | c.*1041G>A | 3'UTR (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
- TULP4 | c.1486+232C>A | Intron (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- TXNDC8 | c.255+2246G>A | Intron (SNP) | VAF 15/172 reads (9%) | catalogued as rs1411455591; called by muse, mutect2
- USP8 | c.*923T>C | 3'UTR (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- WAC | c.*88C>G | 3'UTR (SNP) | VAF 19/177 reads (11%) | called by muse, mutect2, varscan2
- WDR89 | c.-12G>C | 5'UTR (SNP) | VAF 47/150 reads (31%) | called by muse, mutect2, varscan2
- ZCCHC24 | c.*312G>C | 3'UTR (SNP) | VAF 5/112 reads (4%) | called by muse, mutect2
- ZNF24 | c.568+927A>G | Intron (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- ZNF25 | c.*89T>G | 3'UTR (SNP) | VAF 65/175 reads (37%) | called by muse, mutect2, varscan2
- ZNF488 | c.*1959G>A | 3'UTR (SNP) | VAF 14/154 reads (9%) | catalogued as rs1387122129; called by muse, mutect2
- ZNF516 | chr18:76497384 A>C | 5'Flank (SNP) | VAF 4/65 reads (6%) | called by muse, mutect2
- ZNF630 | c.-169G>C | 5'UTR (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
- ZNF662 | c.*1289C>A | 3'UTR (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
